Somatic mutation profile of tumor specimen MMRF_2599_1_BM_CD138pos (aliquot MMRF_2599_1_BM_CD138pos_T1_KHS5U_L12905) from MMRF case MMRF_2599, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.7 years (26,204 days).
Specimen MMRF_2599_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c057c0c7-4358-4f74-a226-58026ad78658.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2599_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2599_1_PB_CD3pos_C3_KHS5U_L12906; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05072602-92a3-48c6-9ea9-bf6d2857c5f1

The open-access MAF lists 99 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 40, Missense Mutation 27, Silent 10, Intron 9, Nonsense Mutation 4, 3'Flank 2, 5'UTR 2, RNA 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CA12 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as rs144831502; called by muse, mutect2, varscan2
- FAT4 | c.7962C>G p.Y2654* | Nonsense Mutation (SNP) | VAF 17/166 reads (10%) | catalogued as COSV58714441; called by muse, mutect2
- HUWE1 | c.8974C>T p.R2992C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1401359685; called by muse, mutect2, varscan2
- LAMA3 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs759176445, COSV58077949; called by muse, mutect2, varscan2
- LONRF3 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 43/131 reads (33%) | catalogued as rs748979369; called by muse, mutect2, varscan2
- NANOS2 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs147396263, COSV100379566; called by muse, mutect2, varscan2
- RBBP7 | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 12/87 reads (14%) | catalogued as COSV66301416; called by mutect2, varscan2
- SCN5A | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 91/387 reads (24%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.936); catalogued as rs763396298, COSV61117571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1323314449; called by muse, mutect2, varscan2
- SPTBN5 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.233); catalogued as rs1330088461; called by muse, mutect2, varscan2
- TMPRSS11E | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs746015990; called by muse, mutect2, varscan2
- UNC5A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1418893349; called by muse, mutect2, varscan2
- ZNF251 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99478121; called by muse, mutect2, varscan2
- ARID1A | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CACNA1B | c.925del p.Q309Sfs*65 | Frame Shift Del (DEL) | VAF 20/135 reads (15%) | called by mutect2, pindel, varscan2
- DCHS1 | c.4894A>T p.T1632S | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- GANC | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 54/294 reads (18%) | PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- GBF1 | c.76T>A p.W26R | Missense Mutation (SNP) | VAF 125/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GPR33 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- IGLV3-25 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- MAP4K5 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.76); called by muse, mutect2
- PCDHAC1 | c.2356G>A p.G786R | Missense Mutation (SNP) | VAF 10/323 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.378); called by muse, mutect2
- PCM1 | c.5995T>A p.C1999S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PDZD2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDZD2 | c.2290T>C p.S764P | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGCZ | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- SHTN1 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIAH1 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC12A2 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- SP100 | c.2147dup p.L716Ffs*14 | Frame Shift Ins (INS) | VAF 38/102 reads (37%) | called by mutect2, pindel, varscan2
- TOX2 | c.1114C>T p.P372S (on ENST00000358131 / NM_001098798.2; = p.P348S on NM_032883.3) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNK2 | c.4023A>C p.E1341D | Missense Mutation (SNP) | VAF 136/225 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF45 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADORA1 | c.45C>T p.I15= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1279473094; called by muse, mutect2, varscan2
- ATP13A1 | c.546T>C p.D182= | Silent (SNP) | VAF 71/213 reads (33%) | called by muse, mutect2, varscan2
- GSC | c.333C>T p.C111= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1418259971; called by muse, mutect2, varscan2
- KRT76 | c.1422C>T p.V474= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs1159417086; called by muse, mutect2, varscan2
- METTL16 | c.1581C>T p.D527= | Silent (SNP) | VAF 106/255 reads (42%) | catalogued as rs372763290; called by muse, mutect2, varscan2
- MSH3 | c.798A>G p.A266= | Silent (SNP) | VAF 68/104 reads (65%) | called by muse, mutect2, varscan2
- MUC16 | c.24873C>T p.S8291= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as rs748849343, COSV101200583; called by muse, mutect2, varscan2
- SLC46A1 | c.843C>T p.H281= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as rs781968978; called by muse, mutect2
- SRRM4 | c.876C>T p.S292= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as COSV57411596; called by muse, mutect2, varscan2
- TENM1 | c.8055G>A p.L2685= | Silent (SNP) | VAF 45/371 reads (12%) | called by muse, mutect2, varscan2
- ACVRL1 | c.*289del | 3'UTR (DEL) | VAF 22/167 reads (13%) | called by pindel, varscan2
- ADGRG5 | n.348G>A | RNA (SNP) | VAF 94/203 reads (46%) | catalogued as rs762580321; called by muse, mutect2, varscan2
- AGPAT3 | c.*3552G>A | 3'UTR (SNP) | VAF 134/272 reads (49%) | catalogued as rs1236122352; called by mutect2, varscan2
- AIF1L | c.*245G>C | 3'UTR (SNP) | VAF 71/102 reads (70%) | called by muse, mutect2, varscan2
- ANLN | c.*608T>G | 3'UTR (SNP) | VAF 118/188 reads (63%) | catalogued as rs904851727; called by muse, mutect2, varscan2
- APLN | c.*1349G>A | 3'UTR (SNP) | VAF 4/66 reads (6%) | catalogued as rs1225554430; called by muse, mutect2
- ARID2 | c.*1968C>A | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- BIVM | c.*1397T>A | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- CDH18 | chr5:19473022 T>G | 3'Flank (SNP) | VAF 25/33 reads (76%) | called by muse, mutect2, varscan2
- CELSR2 | c.6013+19G>A | Intron (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- CHRM3 | c.*608T>A | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- CTNND1 | c.*1385G>A | 3'UTR (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- DCBLD2 | c.*715A>G | 3'UTR (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- DLGAP1 | c.*2369A>T | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- DSEL | c.*1465C>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- ELOVL2 | c.*2305T>G | 3'UTR (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- FBXO15 | c.*72T>G | 3'UTR (SNP) | VAF 143/264 reads (54%) | catalogued as COSV99503455; called by muse, mutect2, varscan2
- FCMR | c.*135T>C | 3'UTR (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- FRMD6 | c.372-96T>C | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- GABRA1 | chr5:161898099 A>G | 3'Flank (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-703A>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- GLCCI1 | c.*2169A>G | 3'UTR (SNP) | VAF 61/180 reads (34%) | called by muse, varscan2
- GLCCI1 | c.*2170A>C | 3'UTR (SNP) | VAF 61/178 reads (34%) | called by muse, varscan2
- HDX | c.*155T>G | 3'UTR (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- HOXB3 | c.-158-1155T>G | Intron (SNP) | VAF 85/161 reads (53%) | called by muse, mutect2, varscan2
- IAPP | c.*240A>G | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- IFIT3 | c.-130C>T | 5'UTR (SNP) | VAF 192/409 reads (47%) | called by muse, mutect2, varscan2
- INSL4 | c.*1277G>T | 3'UTR (SNP) | VAF 52/70 reads (74%) | called by muse, mutect2, varscan2
- KIAA0408 | c.*2092T>G | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- LPAR3 | c.*609dup | 3'UTR (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MANEA | c.*143A>C | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*1935_*1936insATT | 3'UTR (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- RASSF4 | c.374-78T>A | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- RBFOX2 | c.*614T>C | 3'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.2451C>A | RNA (SNP) | VAF 58/894 reads (6%) | called by muse, mutect2
- RLIM | c.*2754G>C | 3'UTR (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*308G>C | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+722C>T | Intron (SNP) | VAF 84/134 reads (63%) | catalogued as rs571967599, COSV73912781; called by muse, mutect2, varscan2
- SEMA3E | c.*783T>G | 3'UTR (SNP) | VAF 115/161 reads (71%) | called by muse, mutect2, varscan2
- SLITRK4 | c.*5520T>G | 3'UTR (SNP) | VAF 40/86 reads (47%) | catalogued as rs1272502967; called by muse, mutect2, varscan2
- SMAP2 | c.*618G>A | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.*22G>A | 3'UTR (SNP) | VAF 202/429 reads (47%) | catalogued as rs571630253, COSV64222971; called by muse, mutect2, varscan2
- TANGO6 | c.-81T>A | 5'UTR (SNP) | VAF 9/28 reads (32%) | catalogued as rs966464951; called by muse, varscan2
- THAP6 | c.*42C>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, varscan2
- TMSB4X | c.-17+220C>T | Intron (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- TPCN2 | c.1540-369C>T | Intron (SNP) | VAF 65/139 reads (47%) | called by muse, mutect2, varscan2
- TRPV6 | c.347-56G>A | Intron (SNP) | VAF 15/216 reads (7%) | catalogued as rs564380145; called by muse, mutect2
- TSHR | c.*118T>C | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- UMPS | c.*614T>C | 3'UTR (SNP) | VAF 31/47 reads (66%) | called by muse, mutect2, varscan2
- WNT5A | c.*4028T>G | 3'UTR (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- ZBED6 | c.*6686G>C | 3'UTR (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- ZFHX4 | c.*2248_*2249insTA | 3'UTR (INS) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- ZFYVE26 | c.*1296A>G | 3'UTR (SNP) | VAF 11/55 reads (20%) | called by mutect2, varscan2
- ZNF576 | c.*489G>C | 3'UTR (SNP) | VAF 16/104 reads (15%) | called by mutect2, varscan2
- ZNF717 | c.*974G>A | 3'UTR (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
